Gene-level copy-number profile of tumor specimen TCGA-22-1017-01A from TCGA case TCGA-22-1017, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.6 years (22,880 days).
Specimen TCGA-22-1017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.18daa90e-46b0-458d-86cd-4dca8dd6edad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-1017-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a5a6599-c271-49cb-b09f-3f265b4e136f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 549; copy number 2: 10,494; copy number 3: 9,545; copy number 4: 23,251; copy number 5: 10,605; copy number 6: 2,160; copy number 7: 1,325; copy number 8: 429; copy number 9: 75; copy number 10: 387; copy number 11: 38; copy number 12: 157; copy number 13: 31; copy number 14: 486; copy number 15: 151; copy number 16: 27; copy number 19: 19; copy number 21: 34; copy number 23: 3; copy number 27: 19; copy number 34: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-22-1017-01): tumor purity 0.34, ploidy 3.33, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,392 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:161,416,297–164,621,482, 31 genes, copy number 13 (within-gene range 7–13): TBR1, AC009487.1, AC009487.2, SLC4A10, AC009487.3, AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46, RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P, GRB14.
- chr2:184,593,577–185,957,063, 11 genes, copy number 12: AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32.
- chr6:53,929,982–54,266,280, 1 gene, copy number 19 (within-gene range 4–19): MLIP.
- chr6:54,190,206–58,438,364, 50 genes, copy number 19–34: AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr8:46,028,804–46,698,688, 5 genes, copy number 12: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4.
- chr8:104,489,231–128,187,101, 275 genes, copy number 10–23 (within-gene range 3–23) (broad region; genes not listed).
- chr8:133,392,211–134,842,637, 32 genes, copy number 9: AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250.
- chr11:66,291,894–69,444,743, 149 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr12:64,497,968–71,800,286, 158 genes, copy number 12–27 (broad region; genes not listed).
- chr14:18,333,726–20,936,255, 151 genes, copy number 15 (broad region; genes not listed).
- chr14:24,505,353–56,650,606, 486 genes, copy number 14 (within-gene range 4–14) (broad region; genes not listed).
- chr19:33,208,664–34,675,699, 43 genes, copy number 9 (within-gene range 5–9): SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21, CHCHD2P3, LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P.

Autosomal genes at a single copy (total copy number 1): 549. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
